Somatic mutation profile of tumor specimen ALCH-B40P-TTP1-A (aliquot ALCH-B40P-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B40P, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.2 years (23,436 days).
Specimen ALCH-B40P-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a92b83ee-084d-4e7d-b1b9-a6c5a835f023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B40P-NB1-A (Blood Derived Normal), aliquot ALCH-B40P-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06a9fbd7-0e53-4847-888f-828bae6389b5

The open-access MAF lists 561 somatic variants for this specimen: 391 protein-altering or splice-affecting, 104 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 325, Silent 104, Nonsense Mutation 28, Intron 23, RNA 20, Splice Site 16, Frame Shift Del 14, 5'UTR 10, Splice Region 6, 5'Flank 5, 3'Flank 4, 3'UTR 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HDAC8 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 64/268 reads (24%) | catalogued as rs886041936; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTC | c.394T>C p.S132P | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs72556253, CM004728; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 76/110 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- USH2A | c.6805+1G>T p.X2269_splice | Splice Site (SNP) | VAF 66/221 reads (30%) | catalogued as rs1553285919; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.2151C>A p.C717* | Nonsense Mutation (SNP) | VAF 30/52 reads (58%) | catalogued as rs776027296, CM062385; called by muse, mutect2, varscan2
- ADGRF4 | c.134C>G p.T45S | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99348014; called by muse, mutect2, varscan2
- ARSF | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 137/447 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs182964743, COSV100839436; called by muse, mutect2, varscan2
- ARX | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.066); catalogued as rs1253162910; called by muse, mutect2
- ASB10 | c.730C>A p.R244S (on ENST00000420175 / NM_001142459.2; = p.R229S on NM_080871.4) | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV51997743, COSV99318781; called by muse, mutect2, varscan2
- ASTN1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV56067894, COSV56075142; called by muse, mutect2, varscan2
- ATP2C1 | c.969G>C p.M323I | Missense Mutation (SNP) | VAF 131/393 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as rs763433370; called by muse, mutect2, varscan2
- AXIN1 | c.1034del p.P345Hfs*69 | Frame Shift Del (DEL) | VAF 97/205 reads (47%) | catalogued as COSV51983922; called by mutect2, pindel, varscan2
- BBX | c.2698G>T p.A900S (on ENST00000325805 / NM_001142568.3; = p.A870S on NM_020235.7) | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs758572861; called by muse, mutect2, varscan2
- C8A | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 75/223 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.331); catalogued as COSV63484264; called by muse, mutect2, varscan2
- CES1 | c.53-1G>A p.X18_splice | Splice Site (SNP) | VAF 111/472 reads (24%) | catalogued as COSV100828819; called by muse, mutect2, varscan2
- CFAP47 | c.4522G>T p.D1508Y | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as COSV100545081; called by muse, mutect2, varscan2
- CGN | c.2852A>G p.E951G | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs780858500; called by muse, mutect2, varscan2
- CLDN10 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV65296459; called by muse, mutect2, varscan2
- CLEC4E | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 181/329 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100222665; called by muse, mutect2, varscan2
- CNDP1 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV62595233; called by muse, mutect2
- CNKSR2 | c.2987T>A p.L996H | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV101070034; called by muse, mutect2, varscan2
- CPXM2 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as rs768048796; called by muse, mutect2, varscan2
- CRB1 | c.1387G>T p.G463C | Missense Mutation (SNP) | VAF 121/412 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66335229; called by muse, mutect2, varscan2
- CSMD3 | c.4326G>T p.M1442I (on ENST00000297405 / NM_001363185.1; = p.M1338I on NM_052900.3) | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.071); catalogued as COSV52100079; called by muse, varscan2
- CSMD3 | c.4285C>G p.P1429A (on ENST00000297405 / NM_001363185.1; = p.P1325A on NM_052900.3) | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV52168764; called by muse, varscan2
- CUBN | c.5492G>T p.R1831I | Missense Mutation (SNP) | VAF 130/384 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs779761719; called by muse, mutect2, varscan2
- DACT1 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 71/125 reads (57%) | catalogued as COSV60022593, COSV60023625; called by muse, mutect2, varscan2
- DEFB134 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 84/153 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as rs773463494; called by muse, mutect2, varscan2
- DENND2A | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV52053497; called by muse, mutect2, varscan2
- DMXL2 | c.3074G>T p.R1025L | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs138911498, COSV51840091; called by muse, mutect2, varscan2
- DNAH7 | c.6823G>C p.D2275H | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV56750036; called by muse, mutect2, varscan2
- DNHD1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375892626; called by muse, mutect2, varscan2
- DPPA4 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100169242; called by muse, mutect2, varscan2
- DYNC1H1 | c.6937G>A p.E2313K | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794797; called by muse, mutect2, varscan2
- DZANK1 | c.655C>A p.P219T (on ENST00000262547 / NM_001099407.1; = p.P20T on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1175618258; called by muse, mutect2, varscan2
- EFCAB5 | c.1826G>T p.R609L | Missense Mutation (SNP) | VAF 84/131 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1376803775, COSV57936370; called by muse, mutect2, varscan2
- EIF3E | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55201312, COSV99622827; called by muse, mutect2, varscan2
- EMILIN3 | c.2162G>A p.R721K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60034905; called by muse, mutect2, varscan2
- EPHA6 | c.388G>C p.V130L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); catalogued as COSV67569079; called by muse, mutect2, varscan2
- FAM186A | c.2234T>C p.V745A | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100525480; called by muse, mutect2, varscan2
- FAT2 | c.5048C>G p.S1683C | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55821589, COSV55824263; called by muse, mutect2, varscan2
- FLG | c.10484C>A p.S3495* | Nonsense Mutation (SNP) | VAF 72/225 reads (32%) | catalogued as COSV64251222; called by muse, mutect2, varscan2
- FOXL2 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100374976; called by muse, mutect2, varscan2
- FOXO1 | c.860G>T p.S287I | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65429481; called by muse, mutect2, varscan2
- FSCB | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs781679494; called by muse, mutect2, varscan2
- GABPB1 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.846); catalogued as rs147105901; called by muse, mutect2, varscan2
- GHSR | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 144/263 reads (55%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.687); catalogued as COSV53837234; called by muse, mutect2, varscan2
- GJA5 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782537233; called by muse, mutect2, varscan2
- GPR42 | c.964C>G p.R322G | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1307654031; called by mutect2, varscan2
- GSG1L | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV66587285; called by muse, mutect2, varscan2
- HECW1 | c.1497G>T p.R499S | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); catalogued as COSV67836873; called by muse, mutect2, varscan2
- HELZ2 | c.6411G>T p.R2137S (on ENST00000467148 / NM_001037335.2; = p.R1568S on NM_033405.3) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs1198585751; called by muse, mutect2, varscan2
- IGKV3-15 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 147/624 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs762878469; called by mutect2, varscan2
- IL2 | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99900816; called by muse, mutect2, varscan2
- IL4I1 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); catalogued as COSV55577954, COSV55578822; called by muse, mutect2, varscan2
- INSM2 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV99354206; called by muse, mutect2, varscan2
- ISL2 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV51959055; called by muse, mutect2, varscan2
- KAT6A | c.3168G>T p.R1056S | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as rs771454272; called by muse, mutect2, varscan2
- KCNT2 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54108291, COSV99654659; called by muse, mutect2, varscan2
- KCNV1 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 85/299 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765741797, COSV52084728; called by muse, mutect2, varscan2
- KIAA1549 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs576958226; called by muse, mutect2, varscan2
- KIF19 | c.2641G>T p.E881* | Nonsense Mutation (SNP) | VAF 133/218 reads (61%) | catalogued as rs1322597784; called by muse, mutect2, varscan2
- KPNB1 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1477492553; called by muse, mutect2
- LAMA4 | c.3541G>A p.E1181K (on ENST00000230538 / NM_001105206.3; = p.E1174K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.864); catalogued as rs958899040; called by muse, mutect2, varscan2
- LINGO4 | c.1727G>T p.R576L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV64313876; called by muse, mutect2, varscan2
- LRRC6 | c.1277C>G p.P426R | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs1206712078, COSV51538726; called by muse, mutect2, varscan2
- LRRK2 | c.5044C>A p.L1682I | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV54166698; called by muse, mutect2
- MAGEE1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV63908832, COSV63910848; called by muse, mutect2
- MAGIX | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs781989177, COSV100891946; called by muse, mutect2
- MAP10 | c.311C>A p.P104Q | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs778484243; called by muse, mutect2, varscan2
- MAP3K9 | c.2905C>T p.P969S (on ENST00000554752 / NM_001284230.1; = p.P983S on NM_033141.4) | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as rs1346743038; called by muse, mutect2, varscan2
- MARCKS | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.048); catalogued as rs763054918; called by muse, mutect2, varscan2
- MBIP | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 122/222 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.104); catalogued as rs1263685666; called by muse, mutect2, varscan2
- MEX3B | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs768510735; called by muse, mutect2, varscan2
- MRM2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54248394; called by muse, mutect2, varscan2
- MUC1 | c.3565-2A>T p.X1189_splice (on ENST00000611571 / NM_001371720.1; = p.X200_splice on NM_002456.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 19/88 reads (22%) | catalogued as rs879028475; called by muse, mutect2, varscan2
- MYRIP | c.1390C>G p.R464G | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as COSV56875183, COSV56881253; called by muse, mutect2, varscan2
- NID2 | c.1840C>A p.H614N | Missense Mutation (SNP) | VAF 117/187 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV53496891, COSV53504093; called by muse, mutect2, varscan2
- OLFM3 | c.595C>A p.L199I (on ENST00000338858 / NM_001288821.1; = p.L179I on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs1186979080; called by muse, mutect2, varscan2
- OLFML2B | c.396C>A p.F132L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV99668191; called by muse, mutect2, varscan2
- OR10K1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780029676, COSV99193971; called by muse, mutect2, varscan2
- OR11H12 | c.489C>A p.C163* | Nonsense Mutation (SNP) | VAF 221/918 reads (24%) | catalogued as COSV73569339; called by muse, varscan2
- OR2G3 | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.049); catalogued as COSV60681560, COSV60681621; called by muse, mutect2, varscan2
- OR2T12 | c.407G>T p.W136L | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.196); catalogued as COSV58780145; called by muse, mutect2, varscan2
- OR2T27 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61280941; called by muse, mutect2, varscan2
- OR2T6 | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764350253; called by muse, mutect2, varscan2
- OR5A1 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57376394; called by muse, mutect2, varscan2
- OR5D14 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs764086281, COSV59455260; called by muse, mutect2, varscan2
- OR5D16 | c.275G>T p.R92I | Missense Mutation (SNP) | VAF 89/157 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV65721690; called by muse, mutect2, varscan2
- OR5F1 | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99079669; called by muse, mutect2, varscan2
- OTUD4 | c.2771C>A p.P924H (on ENST00000447906 / NM_001366057.1; = p.P859H on NM_001102653.1) | Missense Mutation (SNP) | VAF 83/283 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101485949; called by muse, mutect2, varscan2
- PCDH11X | c.2149G>A p.G717R | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100015469; called by muse, mutect2, varscan2
- PER1 | c.2422G>T p.D808Y | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs1476058238; called by muse, mutect2, varscan2
- PIK3C3 | c.2570A>G p.H857R | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs752123097; called by muse, mutect2, varscan2
- PLD2 | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.736); catalogued as rs370990081; called by muse, mutect2, varscan2
- PLEKHH2 | c.2908G>T p.E970* | Nonsense Mutation (SNP) | VAF 27/238 reads (11%) | catalogued as CM145780; called by muse, mutect2, varscan2
- PLXNA4 | c.2564G>A p.C855Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1166417000, COSV100325648, COSV100327778; called by muse, mutect2
- POLR3G | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV67625033; called by muse, mutect2, varscan2
- PRKCB | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as COSV57774525; called by muse, mutect2, varscan2
- PRUNE2 | c.2264C>A p.P755H | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV65038143; called by muse, mutect2, varscan2
- PTMS | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 138/245 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs867073491; called by muse, mutect2, varscan2
- RBM43 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV100508459; called by muse, mutect2, varscan2
- SAYSD1 | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs977041673; called by muse, mutect2
- SDK1 | c.4736G>T p.G1579V | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV67389562; called by muse, mutect2, varscan2
- SDS | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.782); catalogued as COSV57452450; called by muse, mutect2, varscan2
- SEMA3A | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148900275; called by muse, mutect2, varscan2
- SFTPB | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 133/513 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs201986026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIGLEC1 | c.5068C>T p.Q1690* | Nonsense Mutation (SNP) | VAF 39/154 reads (25%) | catalogued as rs1332261276; called by muse, mutect2, varscan2
- SLC13A1 | c.204G>C p.M68I | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1301051863; called by muse, mutect2, varscan2
- SLC22A12 | c.850C>G p.R284G | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM072044; called by muse, mutect2, varscan2
- SLC30A10 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63071343; called by muse, mutect2, varscan2
- SLC35G5 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs757198339; called by muse, mutect2, varscan2
- SLC4A5 | c.2563G>A p.V855I | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs779040076, COSV61029124; called by muse, mutect2, varscan2
- SLITRK3 | c.2048G>C p.R683P | Missense Mutation (SNP) | VAF 199/345 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53845789; called by muse, mutect2, varscan2
- SNTG2 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV57999399; called by muse, mutect2, varscan2
- SPAG11B | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs201164210; called by muse, mutect2, varscan2
- SPAM1 | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV56146557; called by muse, mutect2, varscan2
- SPATA2L | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1435107712; called by muse, mutect2, varscan2
- SPN | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs956933319; called by muse, mutect2, varscan2
- SYMPK | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1368751708; called by muse, mutect2, varscan2
- TBC1D25 | c.2006A>C p.D669A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV100952093; called by muse, mutect2, varscan2
- TBX22 | c.1194C>A p.N398K | Missense Mutation (SNP) | VAF 102/279 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as COSV100960940; called by muse, mutect2, varscan2
- TENM1 | c.3331C>A p.P1111T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV64438420; called by muse, mutect2, varscan2
- THSD7A | c.4887T>C p.A1629= | Splice Region (SNP) | VAF 28/79 reads (35%) | catalogued as COSV101349180; called by muse, mutect2, varscan2
- TNN | c.1684G>T p.V562L | Missense Mutation (SNP) | VAF 126/358 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs141893855, COSV53432891; called by muse, mutect2, varscan2
- TRBV29-1 | c.34+1G>A p.X12_splice | Splice Site (SNP) | VAF 118/337 reads (35%) | catalogued as rs545473233; called by muse, mutect2, varscan2
- TRIM51 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 88/216 reads (41%) | catalogued as COSV55266740; called by muse, mutect2, varscan2
- TRPV2 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58428851; called by muse, mutect2, varscan2
- TTN | c.85433C>A p.P28478Q (on ENST00000591111; = p.P21054Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | PolyPhen probably damaging (0.976); catalogued as COSV100619182; called by muse, mutect2, varscan2
- UGGT2 | c.1978-2A>T p.X660_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as rs1555357869; called by muse, mutect2, varscan2
- VAV2 | c.1814G>T p.G605V (on ENST00000371850 / NM_001134398.2; = p.G595V on NM_003371.4) | Missense Mutation (SNP) | VAF 81/138 reads (59%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.745); catalogued as COSV100895752; called by muse, mutect2, varscan2
- VNN3 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs781255288; called by muse, mutect2, varscan2
- WDR49 | c.657G>T p.W219C (on ENST00000308378 / NM_001366158.1; = p.W560C on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57708693; called by muse, mutect2, varscan2
- WNT11 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 90/168 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV59443658; called by muse, mutect2, varscan2
- ZAN | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); catalogued as rs1280314796; called by muse, mutect2, varscan2
- ZBED9 | c.3332T>C p.I1111T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV71729125; called by muse, mutect2, varscan2
- ZFC3H1 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 56/1740 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1346935634; called by muse, mutect2
- ZNF462 | c.1374A>G p.I458M | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52948757; called by muse, mutect2, varscan2
- ZNF571 | c.762G>C p.K254N | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs763418357; called by muse, mutect2, varscan2
- ZNF609 | c.2385C>G p.I795M | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58587321; called by muse, mutect2, varscan2
- ABCA4 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 298/607 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ABCA9 | c.3717-1G>C p.X1239_splice | Splice Site (SNP) | VAF 53/78 reads (68%) | called by muse, mutect2, varscan2
- ABCB1 | c.841T>A p.L281I | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC090517.4 | c.1310C>G p.P437R | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAN | c.4981C>G p.L1661V | Missense Mutation (SNP) | VAF 137/278 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACSM4 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 110/181 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM19 | c.2441C>A p.A814D | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS14 | c.1480T>A p.L494M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AF196969.1 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.202); called by mutect2, varscan2
- AGA | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 103/195 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AGBL3 | c.2044A>T p.R682W | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- AKR1B1 | c.235-5C>T | Splice Region (SNP) | VAF 73/267 reads (27%) | called by muse, mutect2, varscan2
- AKR1B1 | c.235-6G>T | Splice Region (SNP) | VAF 73/268 reads (27%) | called by muse, mutect2, varscan2
- AL359922.1 | c.348G>C p.R116S | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ALMS1 | c.10385-1G>C p.X3462_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- AMPH | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK2 | c.3952T>C p.Y1318H | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD36 | c.3346G>A p.D1116N | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- AOAH | c.1661T>A p.I554N | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- APC | c.6789A>T p.E2263D | Missense Mutation (SNP) | VAF 107/219 reads (49%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- APOB | c.12517G>A p.D4173N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- APOB | c.7394C>A p.A2465E | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- ARHGAP17 | c.465G>T p.W155C | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ARHGAP30 | c.807C>A p.Y269* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- ARMC8 | c.1588A>G p.K530E (on ENST00000469044 / NM_001363941.2; = p.K516E on NM_015396.6) | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ATN1 | c.2832C>G p.D944E | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.041); called by muse, mutect2
- BABAM1 | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- BEND7 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMX | c.788A>G p.Q263R | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BVES | c.648+1G>T p.X216_splice | Splice Site (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- C1orf105 | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2
- C22orf42 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 119/350 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CABIN1 | c.4718G>T p.C1573F | Missense Mutation (SNP) | VAF 118/382 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- CACNA1F | c.904C>A p.R302S | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CACNA1S | c.78G>T p.R26S | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- CALCOCO2 | c.1176C>T p.L392= | Splice Region (SNP) | VAF 31/54 reads (57%) | called by muse, mutect2, varscan2
- CAPZA1 | c.453A>T p.Q151H | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CASTOR2 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBARP | c.324C>A p.C108* (on ENST00000382477; = p.C114* on NM_152769.3) | Nonsense Mutation (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2, varscan2
- CCDC105 | c.466C>G p.R156G | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CD200R1 | c.299G>C p.C100S (on ENST00000471858 / NM_170780.3; = p.C123S on NM_138806.4) | Missense Mutation (SNP) | VAF 118/346 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD5L | c.820G>T p.G274* | Nonsense Mutation (SNP) | VAF 47/229 reads (21%) | called by muse, mutect2, varscan2
- CDH15 | c.2095del p.Q699Sfs*51 | Frame Shift Del (DEL) | VAF 41/128 reads (32%) | called by mutect2, pindel, varscan2
- CDH23 | c.6803C>A p.P2268Q | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CDKL5 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CDKL5 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 100/301 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CEACAM18 | c.169C>G p.Q57E | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- CEP128 | c.1309C>A p.R437S | Missense Mutation (SNP) | VAF 139/239 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- CEP135 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- CFAP91 | c.2144-1G>A p.X715_splice | Splice Site (SNP) | VAF 124/414 reads (30%) | called by muse, mutect2, varscan2
- CGA | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CPNE4 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CPS1 | c.1837-2A>T p.X613_splice | Splice Site (SNP) | VAF 34/166 reads (20%) | called by muse, mutect2, varscan2
- CPT1C | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CRB1 | c.3131C>G p.P1044R | Missense Mutation (SNP) | VAF 190/601 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPP1 | c.2401G>A p.A801T (on ENST00000676605; = p.A760T on NM_024790.6) | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- CXCR3 | c.880A>T p.S294C | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CXorf65 | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DACH2 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DCAF8L1 | c.641G>C p.S214T | Missense Mutation (SNP) | VAF 74/284 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- DCAF8L2 | c.631del p.A211Qfs*40 | Frame Shift Del (DEL) | VAF 56/229 reads (24%) | called by mutect2, pindel, varscan2
- DGKB | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2, varscan2
- DMKN | c.50del p.G17Afs*31 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel
- DNAH5 | c.8225-1G>C p.X2742_splice | Splice Site (SNP) | VAF 57/118 reads (48%) | called by muse, mutect2, varscan2
- DNAH6 | c.7894G>C p.E2632Q | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DNAH8 | c.4473G>T p.W1491C | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNM2 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 110/1224 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2
- DOK6 | c.593C>A p.S198* | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- DOP1A | c.3552C>G p.C1184W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DPP6 | c.1283C>A p.A428D (on ENST00000377770 / NM_001364500.2; = p.A366D on NM_001936.5) | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- DSC1 | c.2303C>A p.T768N | Missense Mutation (SNP) | VAF 110/379 reads (29%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DTHD1 | c.734C>A p.A245E (on ENST00000456874; = p.A80E on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- DUSP8 | c.1751A>T p.K584M | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- E2F5 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ENAM | c.2102C>A p.P701H | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ESF1 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- F5 | c.652T>C p.F218L | Missense Mutation (SNP) | VAF 129/387 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- FAM204A | c.690G>T p.M230I | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- FAM217A | c.1129_1160del p.Y377Kfs*10 | Frame Shift Del (DEL) | VAF 16/133 reads (12%) | called by mutect2, pindel
- FAM47A | c.1766C>G p.P589R | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- FBXO40 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FCGBP | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FCHO2 | c.2181G>A p.W727* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- FGF4 | c.418_428del p.S140Qfs*11 | Frame Shift Del (DEL) | VAF 48/144 reads (33%) | called by mutect2, pindel, varscan2
- FOXRED2 | c.1133G>C p.G378A | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- FREM3 | c.1844T>A p.L615Q | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FRG1BP | n.726A>G | Splice Region (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- FXYD1 | c.-4-1G>C | Splice Site (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- GABARAPL2 | c.41G>C p.R14T | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRR3 | c.20T>A p.L7* | Nonsense Mutation (SNP) | VAF 60/170 reads (35%) | called by muse, mutect2, varscan2
- GHSR | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 144/265 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GLB1L2 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GOLGB1 | c.7883G>T p.G2628V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GRIK2 | c.1864C>G p.Q622E | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GRM1 | c.2465G>A p.S822N | Missense Mutation (SNP) | VAF 134/448 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HACD1 | c.858G>T p.K286N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- HDX | c.917A>T p.E306V | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HELZ2 | c.6410G>T p.R2137M (on ENST00000467148 / NM_001037335.2; = p.R1568M on NM_033405.3) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- HEPH | c.3200-1G>T p.X1067_splice (on ENST00000343002; = p.X800_splice on NM_014799.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 75/262 reads (29%) | called by muse, mutect2, varscan2
- HERC2 | c.8623G>C p.V2875L | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- HHLA2 | c.796G>T p.G266W | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- IGHM | c.1G>A p.G1R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- IGHV3-53 | c.287C>A p.T96K | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, mutect2
- IGSF9B | c.2509G>T p.A837S | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- IL1RAPL1 | c.2001C>G p.S667R | Missense Mutation (SNP) | VAF 114/315 reads (36%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL20RA | c.142A>T p.I48F | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- INSYN2A | c.241A>T p.R81* | Nonsense Mutation (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- IQCA1 | c.2126C>G p.S709C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- IQCG | c.1166A>T p.Q389L | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- JAK3 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KAT6B | c.1796C>G p.S599C | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- KDM5A | c.2354G>T p.R785M | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KIF13A | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF22 | c.1107C>G p.I369M | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- KIFC1 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KIFC1 | c.814C>A p.L272M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, varscan2
- KIFC1 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIR3DL1 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLF8 | c.487A>G p.I163V | Missense Mutation (SNP) | VAF 113/276 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL4 | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KPNA1 | c.1102G>C p.G368R | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAS1L | c.1170C>A p.H390Q | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LCT | c.2151G>T p.W717C | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- LRP1B | c.6733G>T p.D2245Y | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC9 | c.1641C>G p.G547= | Splice Region (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- MAGEB1 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAGEB17 | c.754C>G p.R252G | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- MAGEC3 | c.1154C>A p.P385Q | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- MALRD1 | c.4628G>T p.G1543V | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MALRD1 | c.5501G>T p.G1834V | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPK10 | c.184C>G p.Q62E (on ENST00000359221 / NM_001351625.2; = p.Q100E on NM_002753.5) | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- MARCHF5 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MAST2 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- MCTP1 | c.2149G>T p.G717C | Missense Mutation (SNP) | VAF 108/208 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MDGA2 | c.2956G>A p.G986R (on ENST00000399232 / NM_001113498.2; = p.G688R on NM_182830.4) | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- MED25 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MROH2B | c.1456C>A p.H486N | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTUS2 | c.122T>A p.M41K | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- MYO7B | c.3041G>T p.W1014L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NEU2 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- NLE1 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 207/297 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- NOP2 | c.168G>T p.L56F | Missense Mutation (SNP) | VAF 118/188 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR2E3 | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- NRK | c.2850T>A p.N950K | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- NRXN1 | c.2909A>C p.N970T | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- OBSCN | c.1755C>G p.F585L | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- OR11A1 | c.292T>A p.C98S | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR2M4 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR2T5 | c.100del p.V34Sfs*7 | Frame Shift Del (DEL) | VAF 68/402 reads (17%) | called by mutect2, varscan2
- OR51E1 | c.691T>A p.L231M | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- OR51E2 | c.640T>A p.S214T | Missense Mutation (SNP) | VAF 97/153 reads (63%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- OR6N2 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- OR8B3 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- OR8B8 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- OTC | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 133/451 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- OXR1 | c.2613G>T p.W871C (on ENST00000442977 / NM_001198532.1; = p.W843C on NM_018002.3) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAMR1 | c.922G>A p.G308S (on ENST00000619888 / NM_001001991.3; = p.G325S on NM_015430.4) | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.935); called by muse, mutect2
- PARD3B | c.2816G>A p.G939E (on ENST00000406610 / NM_001302769.2; = p.G870E on NM_057177.7) | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PAX2 | c.1200del p.A401Pfs*39 (on ENST00000428433 / NM_003987.5; = p.A378Pfs*39 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 34/214 reads (16%) | called by mutect2, pindel, varscan2
- PAX3 | c.1053C>A p.S351R | Missense Mutation (SNP) | VAF 131/446 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PCDHGA2 | c.2295G>C p.K765N | Missense Mutation (SNP) | VAF 102/205 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- PDZD8 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PGAM4 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 105/374 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PHACTR2 | c.638G>T p.S213I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PHF1 | c.74C>A p.S25Y | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- PIEZO1 | c.1910C>A p.T637N | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLCB1 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 98/268 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- POF1B | c.724del p.V242* | Frame Shift Del (DEL) | VAF 19/105 reads (18%) | called by mutect2, pindel, varscan2
- POTEH | c.970G>C p.V324L | Missense Mutation (SNP) | VAF 128/1075 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PPIP5K1 | c.3601A>T p.N1201Y (on ENST00000396923; = p.N1176Y on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2
- PPP1R37 | c.678G>C p.L226F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PRAMEF20 | c.1295A>G p.Q432R | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM11 | c.599A>G p.K200R (on ENST00000530656 / NM_001359633.1; = p.K166R on NM_001256695.1) | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PROSER1 | c.2246C>G p.S749* | Nonsense Mutation (SNP) | VAF 77/221 reads (35%) | called by muse, mutect2
- PRR23C | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGER3 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- PTPN7 | c.11C>A p.A4D (on ENST00000495688; = p.A43D on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRC | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 22/329 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- PTPRD | c.4627C>A p.P1543T | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- PTPRG | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- PZP | c.2565T>A p.C855* | Nonsense Mutation (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2, varscan2
- RAMP2 | c.206G>T p.W69L | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM25 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RBM46 | c.944G>C p.W315S | Missense Mutation (SNP) | VAF 111/197 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBP3 | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RICTOR | c.2967C>G p.N989K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.236); called by muse, mutect2
- RLIM | c.1263C>A p.Y421* | Nonsense Mutation (SNP) | VAF 54/191 reads (28%) | called by muse, mutect2, varscan2
- RNF180 | c.530G>T p.R177I | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF227 | c.385G>C p.G129R | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUNDC3B | c.457A>T p.K153* | Nonsense Mutation (SNP) | VAF 49/176 reads (28%) | called by muse, mutect2, varscan2
- RYR2 | c.1477G>T p.G493* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2
- SALL1 | c.83_84del p.T28Rfs*10 | Frame Shift Del (DEL) | VAF 44/198 reads (22%) | called by pindel, varscan2
- SASH1 | c.2864A>G p.H955R | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SCN7A | c.2320C>A p.P774T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SDCCAG8 | c.1373G>C p.R458P | Missense Mutation (SNP) | VAF 87/326 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SEMG2 | c.679A>G p.R227G | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- SERPINB8 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- SFXN1 | c.850del p.C284Vfs*12 | Frame Shift Del (DEL) | VAF 53/134 reads (40%) | called by mutect2, pindel, varscan2
- SGCA | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 90/150 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- SHANK2 | c.1702G>C p.A568P | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- SHOX | c.651G>C p.Q217H | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SLAIN1 | c.1472C>A p.P491H (on ENST00000466548; = p.P228H on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/431 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC22A18 | c.320C>G p.A107G | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- SLC25A13 | c.1339A>G p.N447D | Missense Mutation (SNP) | VAF 204/545 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SLC25A25 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC26A5 | c.1312-1G>T p.X438_splice | Splice Site (SNP) | VAF 140/433 reads (32%) | called by muse, mutect2, varscan2
- SLC26A8 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- SLC44A5 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- SLC4A5 | c.1166del p.G389Efs*41 | Frame Shift Del (DEL) | VAF 138/310 reads (45%) | called by pindel, varscan2
- SLC5A10 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 57/82 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- SLC5A9 | c.898-1G>T p.X300_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2
- SMC4 | c.1979G>C p.R660T | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- STXBP5 | c.1364A>T p.H455L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYTL5 | c.1451C>A p.T484N | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TCAF1 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.247); called by muse, mutect2
- TECPR1 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TECPR1 | c.1080G>T p.Q360H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TERB2 | c.201C>A p.Y67* | Nonsense Mutation (SNP) | VAF 64/112 reads (57%) | called by muse, mutect2, varscan2
- TEX13C | c.876C>A p.C292* | Nonsense Mutation (SNP) | VAF 50/82 reads (61%) | called by muse, mutect2, varscan2
- TLR8 | c.1208T>C p.I403T (on ENST00000218032 / NM_138636.5; = p.I421T on NM_016610.4) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- TLR8 | c.1616dup p.N539Kfs*3 (on ENST00000218032 / NM_138636.5; = p.N557Kfs*3 on NM_016610.4) | Frame Shift Ins (INS) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- TMEM131L | c.1465T>A p.S489T | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TMEM143 | c.158A>T p.E53V | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNXB | c.8726A>G p.Y2909C (on ENST00000647633; = p.Y2662C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPBGL | c.11del p.R4Pfs*17 | Frame Shift Del (DEL) | VAF 10/19 reads (53%) | called by mutect2, pindel, varscan2
- TRBV19 | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TRIM51 | c.1029G>C p.W343C | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM64B | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by mutect2, varscan2
- TRPC5 | c.2608G>C p.G870R | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.101891C>G p.T33964S (on ENST00000591111; = p.T26540S on NM_003319.4) | Missense Mutation (SNP) | VAF 75/363 reads (21%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.22466C>A p.T7489N (on ENST00000591111; = p.T6562N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TTN | c.18418T>A p.F6140I (on ENST00000591111; = p.F5213I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- TTN | c.11195C>G p.P3732R (on ENST00000591111; = p.P3686R on NM_003319.4) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- UBTFL1 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- UNC13C | c.4708G>C p.D1570H | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC5C | c.2734G>T p.V912F | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UNC79 | c.1053-2A>G p.X351_splice (on ENST00000393151 / NM_001346218.2; = p.X174_splice on NM_020818.5) | Splice Site (SNP) | VAF 83/126 reads (66%) | called by muse, mutect2, varscan2
- USP28 | c.1631G>T p.C544F | Missense Mutation (SNP) | VAF 76/149 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UTP18 | c.1065C>G p.F355L | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS33B | c.1838G>T p.S613I | Missense Mutation (SNP) | VAF 150/255 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- XIRP2 | c.5065A>T p.I1689L (on ENST00000628543; = p.I1864L on NM_152381.6) | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- XK | c.942G>T p.W314C | Missense Mutation (SNP) | VAF 132/439 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XRN1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YTHDF3 | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- ZNF304 | c.1340A>T p.Y447F | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF417 | c.1280A>G p.Q427R | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF451 | c.401_402del p.V134Gfs*15 | Frame Shift Del (DEL) | VAF 40/153 reads (26%) | called by pindel, varscan2
- ZNF536 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF626 | c.1544C>G p.A515G | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF729 | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZSWIM6 | c.3246dup p.G1083Wfs*2 | Frame Shift Ins (INS) | VAF 105/245 reads (43%) | called by mutect2, pindel, varscan2
- A2M | c.3651C>T p.L1217= | Silent (SNP) | VAF 77/548 reads (14%) | called by muse, mutect2, varscan2
- A2ML1 | c.3081G>A p.G1027= | Silent (SNP) | VAF 163/291 reads (56%) | called by muse, mutect2, varscan2
- ABLIM3 | c.1371C>T p.T457= | Silent (SNP) | VAF 66/125 reads (53%) | catalogued as COSV58641961; called by muse, mutect2, varscan2
- ACBD3 | c.507C>T p.C169= | Silent (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- ACTRT2 | c.318C>T p.P106= | Silent (SNP) | VAF 108/232 reads (47%) | catalogued as rs753027340; called by muse, mutect2, varscan2
- ADGRG6 | c.2043C>T p.L681= | Silent (SNP) | VAF 64/211 reads (30%) | catalogued as rs778265059; called by muse, mutect2
- ARHGAP40 | c.1065G>A p.K355= | Silent (SNP) | VAF 74/209 reads (35%) | catalogued as rs866682739; called by muse, mutect2, varscan2
- ARHGEF11 | c.1005G>T p.A335= | Silent (SNP) | VAF 70/149 reads (47%) | catalogued as COSV100809579; called by muse, mutect2, varscan2
- ATF7 | c.172C>T p.L58= | Silent (SNP) | VAF 26/175 reads (15%) | called by muse, mutect2
- ATP8A2 | c.570G>T p.L190= | Silent (SNP) | VAF 19/121 reads (16%) | called by muse, mutect2, varscan2
- BRWD3 | c.603C>T p.D201= | Silent (SNP) | VAF 37/185 reads (20%) | catalogued as rs1309430634; called by muse, mutect2
- C2CD3 | c.2262G>A p.E754= | Silent (SNP) | VAF 180/557 reads (32%) | called by muse, mutect2, varscan2
- CACNG2 | c.969A>G p.V323= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs774312249; called by muse, mutect2, varscan2
- CASR | c.681A>G p.R227= | Silent (SNP) | VAF 89/212 reads (42%) | catalogued as rs766844902; called by muse, mutect2, varscan2
- CCDC168 | c.20112T>A p.R6704= | Silent (SNP) | VAF 53/171 reads (31%) | called by muse, mutect2, varscan2
- CFAP65 | c.1830G>T p.G610= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- CHRDL2 | c.903T>C p.R301= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs768442449; called by muse, varscan2
- CLTC | c.1878A>T p.A626= | Silent (SNP) | VAF 51/93 reads (55%) | called by muse, mutect2, varscan2
- COL18A1 | c.2748G>T p.L916= (on ENST00000359759 / NM_130444.3; = p.L681= on NM_030582.4) | Silent (SNP) | VAF 91/166 reads (55%) | called by muse, mutect2, varscan2
- COL6A5 | c.5307C>A p.V1769= (on ENST00000312481; = p.V1765= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- CPB1 | c.888C>A p.S296= | Silent (SNP) | VAF 347/629 reads (55%) | catalogued as COSV99294464; called by muse, mutect2, varscan2
- CPLX4 | c.357T>C p.D119= | Silent (SNP) | VAF 70/138 reads (51%) | called by muse, mutect2, varscan2
- CPNE7 | c.1215C>A p.I405= | Silent (SNP) | VAF 20/135 reads (15%) | called by muse, varscan2
- CPS1 | c.3624G>T p.L1208= | Silent (SNP) | VAF 84/332 reads (25%) | called by muse, mutect2, varscan2
- CTAG2 | c.525C>A p.V175= | Silent (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2379C>T p.S793= | Silent (SNP) | VAF 56/210 reads (27%) | catalogued as COSV100559514; called by muse, mutect2, varscan2
- CUBN | c.2004C>T p.F668= | Silent (SNP) | VAF 53/191 reads (28%) | catalogued as COSV64708410; called by muse, mutect2, varscan2
- DMD | c.8247A>C p.T2749= | Silent (SNP) | VAF 86/214 reads (40%) | catalogued as rs1176596333; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNM2 | c.1053G>T p.V351= | Silent (SNP) | VAF 107/1210 reads (9%) | called by muse, mutect2
- EPHA3 | c.2439T>C p.V813= | Silent (SNP) | VAF 51/104 reads (49%) | called by muse, mutect2, varscan2
- ERCC3 | c.240C>T p.P80= | Silent (SNP) | VAF 52/175 reads (30%) | catalogued as rs766693494, COSV99573563; called by muse, mutect2, varscan2
- FAM126A | c.1167T>G p.T389= | Silent (SNP) | VAF 79/243 reads (33%) | called by muse, mutect2, varscan2
- FAM155A | c.708G>T p.S236= | Silent (SNP) | VAF 110/382 reads (29%) | catalogued as COSV65593575; called by muse, mutect2, varscan2
- FGD1 | c.1071G>T p.V357= | Silent (SNP) | VAF 52/169 reads (31%) | called by muse, mutect2, varscan2
- FLG | c.9705T>G p.A3235= | Silent (SNP) | VAF 54/300 reads (18%) | catalogued as COSV64248579; called by muse, mutect2, varscan2
- FNDC8 | c.69C>T p.N23= | Silent (SNP) | VAF 41/69 reads (59%) | catalogued as COSV50104449; called by muse, mutect2, varscan2
- FRAT2 | c.621C>T p.G207= | Silent (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- GABARAP | c.300A>G p.E100= | Silent (SNP) | VAF 95/158 reads (60%) | catalogued as COSV56641730; called by muse, mutect2, varscan2
- GPM6A | c.582C>G p.V194= | Silent (SNP) | VAF 10/139 reads (7%) | catalogued as COSV54561626; called by muse, mutect2
- GPX6 | c.282C>A p.V94= | Silent (SNP) | VAF 33/228 reads (14%) | catalogued as COSV62659201; called by muse, mutect2, varscan2
- GRM1 | c.1719A>T p.A573= | Silent (SNP) | VAF 132/409 reads (32%) | called by muse, mutect2, varscan2
- HIGD2B | c.318C>A p.P106= | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- HMCN1 | c.14163A>G p.R4721= | Silent (SNP) | VAF 160/455 reads (35%) | called by muse, mutect2, varscan2
- HTR1B | c.12G>T p.P4= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs192955175, COSV100885449, COSV64051297; called by muse, mutect2, varscan2
- INPP5D | c.816G>A p.L272= (on ENST00000445964 / NM_001017915.3; = p.L271= on NM_005541.5) | Silent (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- INPP5D | c.1875G>A p.R625= (on ENST00000445964 / NM_001017915.3; = p.R624= on NM_005541.5) | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as rs768993106, COSV100857003; called by muse, mutect2, varscan2
- ITGB2 | c.120G>T p.G40= | Silent (SNP) | VAF 60/128 reads (47%) | catalogued as CD120025, COSV100185835; called by muse, mutect2, varscan2
- ITIH6 | c.1614C>A p.A538= | Silent (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- KALRN | c.714G>A p.L238= | Silent (SNP) | VAF 81/208 reads (39%) | catalogued as rs771087549, COSV53760348; called by muse, mutect2, varscan2
- KIF13A | c.3555C>T p.L1185= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV52465250; called by muse, mutect2
- KIFC1 | c.921C>G p.L307= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs766344869; called by muse, varscan2
- KIR3DL1 | c.741G>C p.R247= | Silent (SNP) | VAF 76/252 reads (30%) | called by muse, mutect2, varscan2
- KMT2D | c.2247G>A p.E749= | Silent (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- LAMA4 | c.2070A>T p.A690= (on ENST00000230538 / NM_001105206.3; = p.A683= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 136/353 reads (39%) | called by muse, mutect2, varscan2
- LIMD1 | c.954G>T p.L318= | Silent (SNP) | VAF 56/88 reads (64%) | called by muse, mutect2, varscan2
- LRP8 | c.2016A>G p.P672= | Silent (SNP) | VAF 37/187 reads (20%) | called by muse, mutect2, varscan2
- MAOA | c.534G>A p.V178= | Silent (SNP) | VAF 141/442 reads (32%) | called by muse, mutect2, varscan2
- MARS2 | c.762C>A p.S254= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV99986579; called by muse, mutect2, varscan2
- MED7 | c.222C>T p.H74= | Silent (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- MUC15 | c.36G>A p.T12= | Silent (SNP) | VAF 79/188 reads (42%) | catalogued as rs575183322, COSV55552972; called by muse, mutect2, varscan2
- MUC4 | c.6318C>A p.S2106= | Silent (SNP) | VAF 242/1153 reads (21%) | catalogued as COSV62147494; called by muse, varscan2
- MUC4 | c.6090C>T p.T2030= | Silent (SNP) | VAF 39/986 reads (4%) | called by muse, mutect2
- MYH14 | c.108G>T p.A36= | Silent (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- NDST4 | c.615C>T p.T205= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV99997680; called by muse, mutect2, varscan2
- NLRP4 | c.2067G>C p.V689= | Silent (SNP) | VAF 38/140 reads (27%) | called by muse, mutect2, varscan2
- NUP210L | c.3258A>G p.R1086= | Silent (SNP) | VAF 13/165 reads (8%) | called by muse, mutect2
- OCA2 | c.2418C>T p.F806= | Silent (SNP) | VAF 110/214 reads (51%) | catalogued as COSV100668406; called by muse, mutect2, varscan2
- OLFM1 | c.600C>G p.G200= (on ENST00000371793 / NM_001282611.2; = p.G182= on NM_014279.5) | Silent (SNP) | VAF 19/289 reads (7%) | catalogued as COSV52963577; called by muse, mutect2
- OR10S1 | c.42G>A p.T14= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs748517163, COSV73342691; called by mutect2, varscan2
- OR52R1 | c.225C>G p.V75= | Silent (SNP) | VAF 57/111 reads (51%) | called by muse, mutect2, varscan2
- OTOP1 | c.345C>A p.S115= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as rs1181340249; called by muse, mutect2
- OTUD5 | c.165C>T p.G55= | Silent (SNP) | VAF 53/182 reads (29%) | called by muse, mutect2, varscan2
- OTULINL | c.750A>G p.Q250= | Silent (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- PEG3 | c.3063A>G p.Q1021= | Silent (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- PKD1 | c.11601C>T p.V3867= (on ENST00000262304 / NM_001009944.3; = p.V3866= on NM_000296.4) | Silent (SNP) | VAF 26/42 reads (62%) | called by muse, mutect2, varscan2
- PKD1L2 | c.1299C>A p.T433= | Silent (SNP) | VAF 67/171 reads (39%) | called by muse, mutect2, varscan2
- PKP4 | c.2124G>A p.R708= | Silent (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- PLB1 | c.1446C>G p.V482= | Silent (SNP) | VAF 63/408 reads (15%) | called by muse, mutect2, varscan2
- PLPPR3 | c.2112C>T p.A704= (on ENST00000520876 / NM_001270366.2; = p.A732= on NM_024888.2) | Silent (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- PNLIPRP3 | c.1212C>T p.I404= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs772875821; called by muse, mutect2, varscan2
- POU6F2 | c.421C>T p.L141= | Silent (SNP) | VAF 114/368 reads (31%) | called by muse, mutect2, varscan2
- PRRC2A | c.3318A>G p.S1106= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs746840164; called by muse, mutect2, varscan2
- PTPRN | c.1392C>G p.A464= | Silent (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- PXDNL | c.1479G>T p.S493= | Silent (SNP) | VAF 34/156 reads (22%) | catalogued as COSV62480751; called by muse, mutect2, varscan2
- R3HDM4 | c.666G>T p.L222= | Silent (SNP) | VAF 35/189 reads (19%) | catalogued as COSV64292799; called by muse, mutect2, varscan2
- RFX8 | c.1107C>T p.S369= (on ENST00000646446; = p.S298= on NM_001145664.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 49/162 reads (30%) | called by muse, mutect2, varscan2
- RIMBP2 | c.327A>T p.G109= | Silent (SNP) | VAF 43/70 reads (61%) | called by muse, mutect2, varscan2
- SCN10A | c.3567T>C p.T1189= | Silent (SNP) | VAF 55/115 reads (48%) | catalogued as COSV101479286; called by muse, mutect2, varscan2
- SCN5A | c.5235A>T p.P1745= (on ENST00000333535 / NM_198056.3; = p.P1744= on NM_000335.5) | Silent (SNP) | VAF 79/130 reads (61%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.1240C>A p.R414= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV59479223; called by muse, mutect2, varscan2
- SYTL5 | c.1206C>A p.G402= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs771848343; called by muse, mutect2, varscan2
- TMEM192 | c.769T>C p.L257= | Silent (SNP) | VAF 66/147 reads (45%) | catalogued as rs745475104; called by muse, mutect2, varscan2
- TRPC3 | c.39G>A p.R13= | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- VN1R4 | c.567G>C p.V189= | Silent (SNP) | VAF 35/159 reads (22%) | catalogued as COSV100237433; called by muse, mutect2, varscan2
- VPS39 | c.1981C>A p.R661= (on ENST00000348544 / NM_001301138.2; = p.R650= on NM_015289.5) | Silent (SNP) | VAF 73/138 reads (53%) | called by muse, mutect2, varscan2
- VPS41 | c.1068G>A p.V356= | Silent (SNP) | VAF 47/240 reads (20%) | called by muse, mutect2, varscan2
- VWA5B1 | c.42C>A p.P14= | Silent (SNP) | VAF 59/87 reads (68%) | called by muse, mutect2, varscan2
- WDFY4 | c.1050T>C p.C350= | Silent (SNP) | VAF 57/213 reads (27%) | called by muse, mutect2, varscan2
- WDR72 | c.2631T>A p.T877= | Silent (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- WT1 | c.459C>A p.G153= | Silent (SNP) | VAF 61/171 reads (36%) | called by muse, mutect2, varscan2
- ZBTB7A | c.1080C>T p.H360= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- ZNF267 | c.1179C>T p.S393= | Silent (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- ZNF292 | c.5970A>G p.R1990= | Silent (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- ZNF674 | c.1617T>A p.T539= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- ABCA8 | c.3309+44A>T | Intron (SNP) | VAF 17/20 reads (85%) | called by muse, mutect2, varscan2
- AC026410.1 | n.521G>A | RNA (SNP) | VAF 11/53 reads (21%) | catalogued as rs559563262; called by muse, mutect2, varscan2
- AC114741.1 | n.278G>C | RNA (SNP) | VAF 40/187 reads (21%) | called by muse, mutect2, varscan2
- AK2 | chr1:33008771 T>A | 3'Flank (SNP) | VAF 45/169 reads (27%) | called by muse, mutect2, varscan2
- AL590867.2 | n.136G>A | RNA (SNP) | VAF 101/330 reads (31%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503574 T>C | 5'Flank (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503689 T>C | 5'Flank (SNP) | VAF 34/93 reads (37%) | called by muse, mutect2, varscan2
- C12orf76 | n.468G>T | RNA (SNP) | VAF 124/205 reads (60%) | catalogued as COSV58367965; called by muse, mutect2, varscan2
- CA5BP1 | n.411G>C | RNA (SNP) | VAF 47/150 reads (31%) | called by muse, mutect2, varscan2
- CABCOCO1 | chr10:61662940 G>A | 5'Flank (SNP) | VAF 7/39 reads (18%) | catalogued as rs933274800; called by muse, mutect2, varscan2
- CENPB | chr20:3787088 A>G | 5'Flank (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- CHRM2 | c.-47+33862C>A | Intron (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811950 G>T | 3'Flank (SNP) | VAF 76/203 reads (37%) | called by muse, mutect2, varscan2
- CLYBL | c.634+77C>T | Intron (SNP) | VAF 125/412 reads (30%) | called by muse, varscan2
- CYP7A1 | c.-26C>T | 5'UTR (SNP) | VAF 45/131 reads (34%) | called by muse, mutect2, varscan2
- DCC | c.4254+34G>A | Intron (SNP) | VAF 110/261 reads (42%) | called by muse, mutect2, varscan2
- DEFB126 | c.-21T>C | 5'UTR (SNP) | VAF 53/126 reads (42%) | called by muse, mutect2, varscan2
- DNM2 | c.1336-1013C>G | Intron (SNP) | VAF 116/1236 reads (9%) | called by muse, mutect2
- FLT1 | c.*1A>T | 3'UTR (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- FYB1 | c.1907+1671G>T | Intron (SNP) | VAF 64/135 reads (47%) | called by muse, mutect2, varscan2
- GCSAML | c.-56-10402C>G | Intron (SNP) | VAF 64/219 reads (29%) | called by muse, mutect2, varscan2
- GRIA4 | c.2295-5868G>A | Intron (SNP) | VAF 81/147 reads (55%) | called by muse, mutect2, varscan2
- HDAC8 | c.1111+521C>A | Intron (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- HK2 | c.375+16C>T | Intron (SNP) | VAF 137/489 reads (28%) | called by muse, mutect2, varscan2
- HOXB4 | chr17:48579942 C>G | 5'Flank (SNP) | VAF 64/167 reads (38%) | called by muse, mutect2, varscan2
- KMO | c.-62A>C | 5'UTR (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- LINC02313 | n.321G>C | RNA (SNP) | VAF 59/99 reads (60%) | called by muse, mutect2, varscan2
- LINC02877 | n.381C>T | RNA (SNP) | VAF 20/130 reads (15%) | catalogued as rs1202418606; called by muse, mutect2, varscan2
- MIR487B | n.10G>T | RNA (SNP) | VAF 42/68 reads (62%) | called by muse, mutect2, varscan2
- MOSPD2 | c.79+12G>C | Intron (SNP) | VAF 58/203 reads (29%) | called by muse, mutect2, varscan2
- MSC-AS1 | n.536C>A | RNA (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- MUC20P1 | n.1294C>T | RNA (SNP) | VAF 53/489 reads (11%) | called by muse, mutect2, varscan2
- MYL3 | chr3:46833973 C>A | 3'Flank (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1001T>A | RNA (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- NOVA1 | c.280+45669A>T | Intron (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- OFCC1 | n.1412G>C | RNA (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- OR2M1P | n.399C>G | RNA (SNP) | VAF 75/191 reads (39%) | called by muse, mutect2, varscan2
- OR52Z1 | n.358C>A | RNA (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- OR52Z1 | n.357C>A | RNA (SNP) | VAF 28/56 reads (50%) | catalogued as rs762847213; called by muse, mutect2, varscan2
- PARGP1 | n.1637G>C | RNA (SNP) | VAF 33/205 reads (16%) | called by muse, mutect2, varscan2
- PLCE1 | c.1810-37G>T | Intron (SNP) | VAF 58/159 reads (36%) | called by muse, mutect2, varscan2
- PPP1R21 | c.127-13C>T | Intron (SNP) | VAF 44/214 reads (21%) | called by muse, mutect2, varscan2
- PRRC2C | c.8199+897G>T | Intron (SNP) | VAF 76/212 reads (36%) | called by muse, mutect2, varscan2
- PTCH2 | c.-51G>T | 5'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- REEP6 | c.-14G>T | 5'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- RFPL4AP1 | n.396G>A | RNA (SNP) | VAF 114/354 reads (32%) | called by muse, mutect2, varscan2
- RFX4 | c.-16T>C | 5'UTR (SNP) | VAF 24/38 reads (63%) | called by muse, mutect2, varscan2
- RFX6 | c.*20G>T | 3'UTR (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- RNF111 | c.2867+809G>C | Intron (SNP) | VAF 50/142 reads (35%) | catalogued as rs1237308510; called by muse, mutect2, varscan2
- SATB2 | c.347-15936C>A | Intron (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- SATB2 | c.347-15937G>A | Intron (SNP) | VAF 20/108 reads (19%) | catalogued as rs961876768; called by muse, mutect2, varscan2
- SDHAF2 | c.-7G>T | 5'UTR (SNP) | VAF 93/396 reads (23%) | called by muse, mutect2, varscan2
- SLC14A1 | c.342-39C>T | Intron (SNP) | VAF 107/216 reads (50%) | catalogued as rs775601456; called by muse, mutect2, varscan2
- SNORD115-38 | n.72C>G | RNA (SNP) | VAF 64/123 reads (52%) | catalogued as rs565650395; called by muse, mutect2, varscan2
- SPATA31C1 | n.813G>T | RNA (SNP) | VAF 82/186 reads (44%) | called by muse, mutect2, varscan2
- SSH2 | c.64-54985A>G | Intron (SNP) | VAF 40/69 reads (58%) | catalogued as COSV52177176; called by muse, mutect2, varscan2
- SSR1 | c.*62G>T | 3'UTR (SNP) | VAF 51/111 reads (46%) | called by muse, mutect2, varscan2
- SYT7 | c.215+4199G>C | Intron (SNP) | VAF 36/120 reads (30%) | called by muse, mutect2, varscan2
- TCP11 | c.124+210G>C | Intron (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- TEX101 | c.-2G>T | 5'UTR (SNP) | VAF 17/41 reads (41%) | catalogued as COSV53662381; called by muse, mutect2, varscan2
- TMCO1 | c.*912C>T | 3'UTR (SNP) | VAF 40/208 reads (19%) | called by muse, mutect2, varscan2
- TRAV1-2 | c.-24del | 5'UTR (DEL) | VAF 120/261 reads (46%) | called by mutect2, pindel, varscan2
- TTC5 | c.-6del | 5'UTR (DEL) | VAF 87/218 reads (40%) | catalogued as rs747844127; called by pindel, varscan2
- TTN | c.10360+5089C>A | Intron (SNP) | VAF 51/249 reads (20%) | catalogued as COSV100633552; called by muse, mutect2, varscan2
- TUBBP5 | n.1192G>C | RNA (SNP) | VAF 60/154 reads (39%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071548 G>T | 3'Flank (SNP) | VAF 165/497 reads (33%) | called by muse, mutect2, varscan2
